Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8325, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8325-01A (Primary Tumor).

[page 1 of 2]
Other Related Data:

Billing Type:
Financial Number:

Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

- 1: SP: Left kidney and adrenal
- 2: SP: Portion of left 11th rib
- 3: SP: Left para-aortic lymph node

DIAGNOSIS:

- 1) KIDNEY, LEFT; RESECTION:
- RENAL CELL CARCINOMA, CHROMOPHOBE CELL TYPE.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 15.8 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- NO ADRENAL GLAND IS IDENTIFIED.
- 2) RIB, PORTION LEFT ELEVENTH; BIOPSY:
- GROSSLY UNREMARKABLE. SECTIONS NOT YET READY BECAUSE OF NEED TO DECALCIFY. IF SIGNIFICANT MICROSCOPIC ABNORMALITIES ARE FOUND, AN ADDENDUM REPORT WILL BE ISSUED.
- 3) LYMPH NODE, LEFT PARA-AORTIC; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description

- 1) The specimen is received fresh, labeled "Left Kidney and Adrenal". It consists of a kidney distorted by a cortical tumor. The non-neoplastic kidney measures 13.3 x 4.1 x 3.2 cm. The renal cortical tumor measures 15.8 x 13.8 x 6.2 cm. It has a uniform solid mahogany appearance on cut section with a central

[page 2 of 2]
scar. The specimen is photographed and representative sections of the tumor are taken for TPS as well as cytogenetics and electron microscopy. The tumor is well-circumscribed attached to the kidney with a pseudocapsule. There is an attached ureter measuring roughly 9.3 cm in length by 0.3 cm in diameter with perinephric adipose tissue measuring 10.5 x 11.0 x 4.2 cm. No obvious palpable lymph nodes are present within this fat. There is no obvious adrenal gland is identified. Representative sections are submitted as per summary of sections.

Summary of Sections:

FSC - Frozen Section Control
UVM - Ureteral and Vascular Margins
K - Non-neoplastic Kidney with Perinephric Fat
T - Tumor

2) The specimen is received fresh, labeled "Portion of Left 11th Rib". It consists of 7.5 x 1.0 x 0.7 cm portion of bone with attached soft tissue. No gross abnormalities are noted. Representative sections are submitted following decalcification.

Summary of Sections:

RIB - rib

3) The specimen is received in formalin, labeled "Left Para-aortic Lymph Node". It consists of fragments of firm tan tissue in aggregate measuring 2.5 x 2.1 x 0.4 cm. It is entirely submitted.

Summary of Sections:

LN - Specimen in toto

Histo Stain Results/Comments:

Stain/Procedure Name	Result	Comment
RECUT ADDITIONAL H&E		

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSC		1	M	N
	K		2	M	
	T		7	M	
	UVM		1	M	
2	RIB		1	1	N
3	ln		1	M	Y

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: FAVOR ONCOCYTOMA.
PERMANENT DIAGNOSIS: SEE FINAL DIAGNOSIS.

Source: NCI Genomic Data Commons file 1f10350f-6165-444d-991d-9aa467f3450c (TCGA-KL-8325.E148EB96-A6C1-4748-88AE-B4F95743F3C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).